Surgical pathology report (de-identified scan), TCGA case TCGA-C4-A0EZ, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Indivumed, specimen TCGA-C4-A0EZ-01A (Primary Tumor).

100-0-3

Carcinoma, urothelial, NOS 8120/3

Site: bladder, NOS C67.9 1/28/11 hu

Diagnosis

1. Cystectomy preparation with infiltration of a small-cell urothelial carcinoma (90% of the tumor shows small-cell morphology), measuring a maximum of 4.5 cm, with microscopic infiltration of the perivesical fatty tissue and tumor infiltration of the lymph vessels (L1). Remaining urothelium with multifocal carcinoma in situ.

Tumor-free surgical resection lines.

A lymph node metastasis (measuring 0.9 cm) in the perivesical fatty tissue.

2. Carcinoma-free fatty tissue with fibrosis (peritoneum).

3. Carcinoma-free right ureter resection material.

4. Carcinoma-free left ureter resection material.

Comment:

Summary tumor classification (in light of the frozen section material sent in under -----):
pT3a, pN1 (1/16), L1, V0; G3

Follow-up report:

Diagnosis communicated to date:

on 3. (bladder tumor): extensive, poorly differentiated, in part small-cell urothelial carcinoma. Foci of urothelial lining with carcinoma in situ.
Small parts of tumor-free bladder wall.

As announced, the material has in the meantime undergone immunohistochemical analysis for more detailed characterization of the urothelial carcinoma (P53, CK20, S-100, synaptophysin, EMA, AE1/AE3, chromatogranin, NSE)

The tumor infiltrates are diffusely positive for pan-cytokeratin AE1/AE3. Parts of the tumor are highly positive for synaptophysin and NSE and negative for chromatogranin, S-100 and CK20. Parts of the tumor are highly positive for P53.

The immunohistochemical marker constellation also confirms the diagnosis of small-cell urothelial carcinoma already communicated.

Source: NCI Genomic Data Commons file 2939ff48-36de-4979-b137-113b2ed74c81 (TCGA-C4-A0EZ.DB053F32-6DBF-45A8-AF18-4DF817CB6444.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).